Gene-level copy-number profile of tumor specimen TCGA-24-1556-01A from TCGA case TCGA-24-1556, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 50.7 years (18,517 days).
Specimen TCGA-24-1556-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.30477fb0-3b9b-4b2e-aeff-69d84d2b2647.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1556-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fbf1344f-1122-4c7b-957b-4e163670ce14

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 874; copy number 2: 13,286; copy number 3: 22,482; copy number 4: 13,783; copy number 5: 6,685; copy number 6: 1,612; copy number 7: 1,006; copy number 8: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1556-01): tumor purity 0.82, ploidy 3.38, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:112,819,147–115,682,618, 25 genes: BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1, AC073348.2, PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,071 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–15,446,167, 354 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:37,005,646–40,715,363, 63 genes, copy number 7 (broad region; genes not listed).
- chr8:58,490,178–60,623,644, 24 genes, copy number 7 (within-gene range 5–7): CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3.
- chr8:63,384,839–71,815,625, 126 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:71,841,549–71,844,468, 1 gene, copy number 7: MSC.
- chr11:121,292,681–131,350,917, 245 genes, copy number 7–8 (broad region; genes not listed).
- chr11:131,385,249–131,771,638, 5 genes, copy number 8: RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1.
- chr15:90,529,923–101,933,350, 253 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 603. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
